RC case RC-B659 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d999c175-9321-487e-8a96-b1c56b7c10cd

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1971; Vital status: Alive; Country of birth: Antigua and Barbuda.

Diagnoses (1)
1. Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants): ICD-O-3 morphology code: 9827/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 44.2 years (16,159 days); Year of diagnosis: 2016; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Weight Loss; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Lymph Node, Axillary / Lymph Node, Inguinal / Lymph Node, Mediastinal / Bone, NOS / Peripheral blood / Cerebrospinal fluid.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: EPOCH; Days to treatment start: 13 days; Days to treatment end: 104 days; Number of cycles: 4; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 13 days; Days to treatment end: 104 days; Number of cycles: 4; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 116 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine; Initial disease status: Initial Diagnosis; Days to treatment start: 151 days; Days to treatment end: 433 days (1.2 years); Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.

Follow-up (3 entries)
- Days to follow up: 90 days; Disease response: Tumor Free.
- Day 2,016 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Days to follow up: 2,455 days (6.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Epstein-Barr Virus: Negative [Test analyte type: DNA].
- Lactate Dehydrogenase 2621 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis B Infection.
- Timepoint category: Initial Diagnosis; Weight: 59 kg; Height: 155 cm; BMI: 24.6.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample RC-B659-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B659-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
